CCDI case PBCGFM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/069e31de-0ed4-4eaa-8220-95aac491f643

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 7.1 years (2,609 days).

Biospecimens (2 samples)
- Sample 0DRL0X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRL1L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
